Somatic mutation profile of tumor specimen TARGET-40-0A4HXS-01A (aliquot TARGET-40-0A4HXS-01A-01Y) from TARGET case TARGET-40-0A4HXS, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 23.2 years (8,470 days).
Specimen TARGET-40-0A4HXS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a3c1eea-4b0d-4084-b93d-973b2cd6989e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4HXS-10A (Blood Derived Normal), aliquot TARGET-40-0A4HXS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3356da9-3016-43ce-9d70-f12c4036c121

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MMP2 | c.1769G>A p.R590K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV54598835; called by muse, varscan2
- YTHDC1 | c.1666G>A p.E556K (on ENST00000344157 / NM_001031732.4; = p.E538K on NM_133370.4) | Missense Mutation (SNP) | VAF 35/35 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs1243603217; called by mutect2, varscan2
- FNDC3B | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- RAPGEFL1 | c.1335+32dup | Intron (INS) | VAF 3/20 reads (15%) | called by pindel, varscan2
